Somatic mutation profile of tumor specimen TCGA-BJ-A45F-01A (aliquot TCGA-BJ-A45F-01A-12D-A23U-08) from TCGA case TCGA-BJ-A45F, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 59.4 years (21,713 days).
Specimen TCGA-BJ-A45F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ab019c3-e3fe-47e2-9204-c4cc08e683c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A45F-10A (Blood Derived Normal), aliquot TCGA-BJ-A45F-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df051f13-5507-45d3-9564-f7947c83115f

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 32/78 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CD93 | c.1594C>G p.L532V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV55664502; called by muse, mutect2, varscan2
- EEF1A1 | c.670A>G p.S224G | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV58549339; called by muse, mutect2, varscan2
- GRAMD2A | c.1013A>G p.E338G | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59033352; called by muse, mutect2, varscan2
- SPECC1 | c.148C>A p.L50I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.299); catalogued as COSV54956392; called by muse, mutect2, varscan2
- TG | c.3737A>C p.Q1246P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV55072562; called by muse, mutect2, varscan2
- ZMIZ2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs780358891, COSV54807155; called by muse, mutect2, varscan2
- CCDC105 | c.1002C>T p.A334= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs959338102, COSV52963712; called by muse, mutect2
